Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BP, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BP-01A (Primary Tumor).

hw 10/15/11		

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

LEFT THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Isthmus, Left lobe

HISTOLOGIC TYPE:

Papillary carcinoma, conventional type

FOCALITY:

Multifocal: 2.5 cm - left lobe; 1.2cm - isthmus

LYMPH NODES:

Metastatic carcinoma in 2 of 3 perithyroidal lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to regional lymph nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest

margin: <1 mm (posterior margin)

VENOUS/LYMPHATIC INVASION: Present

1CD-0-3
Carcinoma, papillary, thyroid
8260/3

Site: thyroid, nos C73.9

hw
10/15/11

Source: NCI Genomic Data Commons file 350e0411-c888-4da4-bd1e-f224ffde9fb2 (TCGA-ET-A3BP.111885BE-27BA-4EDA-9AAE-53308A6BE629.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).